Somatic mutation profile of tumor specimen TCGA-HW-7490-01A (aliquot TCGA-HW-7490-01A-11D-2024-08) from TCGA case TCGA-HW-7490, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.3 years (15,092 days).
Specimen TCGA-HW-7490-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4a8f7e7-a3ad-46e3-8d4f-7bfe17d2bbfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-7490-10A (Blood Derived Normal), aliquot TCGA-HW-7490-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/136cf993-8324-4e60-916b-6bea23aa5760

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 16, Silent 11, Frame Shift Del 8, In Frame Del 4, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KMT2D | c.4135_4136del p.M1379Vfs*52 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs398123744, COSV56408470; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 29/32 reads (91%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1417_1419del p.F473del | In Frame Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs758600630; called by pindel, varscan2
- CEACAM4 | c.534G>T p.R178S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs782159542, COSV99701162; called by muse, varscan2
- FRY | c.8469+1G>C p.X2823_splice | Splice Site (SNP) | VAF 17/119 reads (14%) | catalogued as COSV66580016; called by muse, mutect2, varscan2
- GRIN2B | c.3371G>A p.R1124K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV74207782; called by muse, mutect2, varscan2
- HSDL1 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV54741767, COSV54742208; called by muse, mutect2
- LENG9 | c.1246_1247del p.Q416Vfs*58 | Frame Shift Del (DEL) | VAF 38/100 reads (38%) | catalogued as rs778740821; called by mutect2, pindel, varscan2
- MMP1 | c.627G>A p.E209= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as COSV59511801; called by muse, mutect2, varscan2
- OR2M7 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV58739627; called by muse, mutect2
- OR4A15 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.034); catalogued as rs1300069646, COSV59034110, COSV59037616; called by muse, mutect2, varscan2
- PALD1 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs192719429, COSV54978854; called by muse, mutect2, varscan2
- PPIAL4G | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.127); catalogued as rs587707407; called by muse, mutect2, varscan2
- PRB2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs781764435, COSV101231473; called by muse, mutect2, varscan2
- PTCHD4 | c.676T>A p.F226I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.205); catalogued as COSV59777392; called by muse, mutect2, varscan2
- RPS4Y2 | c.414C>A p.H138Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56488960; called by muse, mutect2, varscan2
- RUNX1T1 | c.446G>A p.R149H (on ENST00000265814 / NM_001198628.1; = p.R122H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as rs757828605, COSV56149246; called by muse, mutect2, varscan2
- SLC6A11 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV54398954; called by muse, mutect2
- XKR9 | c.529T>C p.W177R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV68773525; called by muse, mutect2
- ZBED9 | c.2872T>C p.C958R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.99); catalogued as rs770317152, COSV71729769; called by muse, mutect2, varscan2
- AMOTL2 | c.2074_2076del p.T692del | In Frame Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- ATRX | c.4014_4015del p.H1338Qfs*11 | Frame Shift Del (DEL) | VAF 19/29 reads (66%) | called by mutect2, pindel, varscan2
- BTBD1 | c.594_595del p.C199Sfs*19 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, varscan2
- CYP3A7 | c.752_753del p.K251Ifs*26 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- EPB41L1 | c.50_52del p.E17del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by pindel, varscan2
- RANBP6 | c.2506_2507del p.L836Afs*3 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by pindel, varscan2
- RMDN1 | c.453_454del p.R152Sfs*6 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- UHRF2 | c.1685_1688del p.V562Efs*2 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- USP9X | c.7285_7287del p.R2429del | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- ACAD10 | c.3003G>A p.P1001= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as rs750301886, COSV58163033; called by muse, mutect2, varscan2
- APRT | c.228C>T p.A76= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs1336446072, COSV51940461; called by muse, mutect2
- CDH17 | c.1047C>T p.V349= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as rs1207840260, COSV50340913; called by muse, mutect2, varscan2
- CDK14 | c.990T>A p.A330= (on ENST00000380050 / NM_001287135.2; = p.A312= on NM_012395.3) | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as COSV56051725; called by muse, mutect2, varscan2
- FAM78A | c.579G>A p.L193= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV55993277; called by muse, mutect2, varscan2
- FRMD7 | c.1047A>G p.K349= | Silent (SNP) | VAF 87/119 reads (73%) | catalogued as COSV53748754; called by muse, mutect2, varscan2
- GPR39 | c.681C>T p.A227= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV61428871; called by muse, mutect2, varscan2
- KRT84 | c.735C>T p.V245= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs1270344793, COSV57773697; called by muse, mutect2, varscan2
- MAN2B2 | c.2518C>T p.L840= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV53456735; called by muse, mutect2, varscan2
- PHF23 | c.699A>G p.P233= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as COSV50039670; called by muse, mutect2, varscan2
- USH2A | c.11559A>G p.G3853= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV56434173; called by muse, mutect2, varscan2
